Somatic mutation profile of tumor specimen TCGA-17-Z007-01A (aliquot TCGA-17-Z007-01A-01W-0746-08) from TCGA case TCGA-17-Z007, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z007-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1cc37bd7-7f9c-4cb9-8e9f-90f0a7f8de08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z007-11A (Solid Tissue Normal), aliquot TCGA-17-Z007-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cebdaf8a-6798-4827-8b07-07c74cf7d4e1

The open-access MAF lists 66 somatic variants for this specimen: 50 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 14, Nonsense Mutation 4, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.745A>G p.R249G | Missense Mutation (SNP) | VAF 17/57 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.12128G>A p.R4043H | Missense Mutation (SNP) | VAF 36/306 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs766530816, COSV71283192; called by muse, mutect2, varscan2
- CCDC105 | c.1205A>G p.Q402R | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs534491257; called by muse, mutect2, varscan2
- COL11A2 | c.3092C>T p.P1031L (on ENST00000341947 / NM_080680.3; = p.P924L on NM_080679.2) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.024); catalogued as rs528009333; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CWC25 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs748735255; called by mutect2, varscan2
- DMD | c.2468T>G p.L823R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.056); catalogued as COSV100818002; called by muse, mutect2, varscan2
- DPYD | c.441G>T p.E147D | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV60075662; called by muse, mutect2, varscan2
- DSCAM | c.1765G>A p.V589I | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.32); catalogued as rs200358160, COSV68028771; called by muse, mutect2, varscan2
- IGKV2-28 | c.355A>T p.T119S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs763278232; called by mutect2, varscan2
- IQGAP3 | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs767495280; called by muse, mutect2
- IRAK3 | c.1580G>T p.R527I | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV54159675; called by muse, mutect2
- LRRTM4 | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69139932, COSV69141009; called by muse, mutect2, varscan2
- LTBP1 | c.2789G>A p.R930H (on ENST00000404816 / NM_206943.4; = p.R604H on NM_000627.4) | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.97); catalogued as rs368736095; called by muse, mutect2, varscan2
- MYH2 | c.3517C>T p.R1173W | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767243766, COSV55434229; called by muse, mutect2, varscan2
- MYH4 | c.2468G>A p.R823H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs557134943, COSV55126346; called by muse, mutect2, varscan2
- NACA2 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs767833660, COSV71713104; called by muse, mutect2
- NELL1 | c.1020A>T p.K340N | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.787); catalogued as COSV54236708, COSV54263958; called by muse, mutect2
- PCDHA11 | c.1387G>A p.V463M | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.908); catalogued as rs372818492; called by muse, mutect2, varscan2
- PCLO | c.4144C>T p.P1382S | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV61623807; called by muse, mutect2, varscan2
- PKHD1L1 | c.3057G>C p.K1019N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as rs1211307200; called by muse, mutect2
- PNPLA5 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs749917334, COSV99336671; called by muse, mutect2, varscan2
- PSMD1 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as COSV58079915; called by muse, mutect2
- RAB2B | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs773462475; called by muse, mutect2, varscan2
- SCG2 | c.146A>C p.K49T | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.224); catalogued as rs1462019509, COSV59539101; called by muse, mutect2, varscan2
- SLC6A15 | c.1918C>T p.R640C | Missense Mutation (SNP) | VAF 61/252 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs772296811, COSV57019493; called by muse, varscan2
- SLC9A1 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as rs150618776; called by muse, mutect2, varscan2
- SPOCK1 | c.884A>G p.K295R | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.908); catalogued as rs1390694131, COSV56447502; called by muse, varscan2
- TARBP1 | c.4258G>A p.E1420K | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs201832385; called by mutect2, varscan2
- TLN1 | c.3107C>T p.T1036M | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs1391200571; called by muse, mutect2, varscan2
- TTN | c.18439G>T p.G6147* (on ENST00000591111; = p.G5220* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV60128494; called by muse, mutect2, varscan2
- ACAD8 | c.619A>G p.T207A | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- CNTN5 | c.2780A>G p.K927R | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DCLK3 | c.1931T>A p.V644E | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- EFCAB13 | c.970A>T p.S324C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- FLG | c.11972T>A p.F3991Y | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.175); called by muse, mutect2
- GLUD2 | c.374A>G p.D125G | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- HECTD4 | c.4122G>A p.M1374I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- HSPA5 | c.1082T>A p.L361H | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL40 | c.1787T>C p.V596A | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); called by muse, mutect2
- METTL25 | c.915T>G p.N305K | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MOCS3 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO9A | c.6784G>C p.E2262Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- NBEA | c.1640G>T p.G547V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.736); called by muse, mutect2
- NEU3 | c.481T>G p.F161V | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PCDHB1 | c.1637T>G p.V546G | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- PDE3A | c.1358T>A p.L453* | Nonsense Mutation (SNP) | VAF 10/98 reads (10%) | called by muse, mutect2
- POLQ | c.1078G>C p.E360Q | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- PRDM16 | c.1203G>C p.K401N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SACS | c.5323G>T p.A1775S | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.272); called by muse, mutect2
- USP44 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- AGTR2 | c.735G>T p.G245= | Silent (SNP) | VAF 10/202 reads (5%) | called by muse, mutect2
- ATP8A2 | c.2859C>G p.G953= | Silent (SNP) | VAF 19/131 reads (15%) | called by muse, mutect2, varscan2
- DOP1A | c.1410C>A p.T470= | Silent (SNP) | VAF 13/159 reads (8%) | catalogued as COSV52707955; called by muse, mutect2
- FMNL2 | c.1743T>A p.T581= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- GAB2 | c.1146C>T p.V382= (on ENST00000361507 / NM_080491.3; = p.V344= on NM_012296.3) | Silent (SNP) | VAF 4/88 reads (5%) | called by muse, mutect2
- GJA8 | c.297C>T p.Y99= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as rs142426709; called by muse, mutect2, varscan2
- GLP2R | c.327T>G p.S109= | Silent (SNP) | VAF 16/170 reads (9%) | catalogued as rs920376781, COSV52321551; called by muse, mutect2
- MON2 | c.2436G>A p.L812= | Silent (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- OGDH | c.2937C>T p.R979= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as rs751284653, COSV56053364; called by mutect2, varscan2
- PGBD2 | c.1089G>A p.L363= | Silent (SNP) | VAF 31/144 reads (22%) | called by muse, mutect2, varscan2
- PPEF2 | c.1617C>T p.N539= | Silent (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- PRRC2B | c.3735C>T p.C1245= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs770584731, COSV61934509; called by muse, mutect2, varscan2
- ROBO1 | c.588C>A p.G196= | Silent (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- TSPEAR | c.1422C>T p.S474= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs375066240; called by muse, mutect2, varscan2
- COCH | c.928+366T>A | Intron (SNP) | VAF 12/125 reads (10%) | called by muse, mutect2, varscan2
- COCH | c.928+367G>A | Intron (SNP) | VAF 12/125 reads (10%) | catalogued as rs868695125; called by muse, mutect2, varscan2
